Gene-level copy-number profile of tumor specimen ALCH-ADOB-TTP1-A from ALCHEMIST case ALCH-ADOB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.4 years (25,357 days).
Specimen ALCH-ADOB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6fc7f8f8-883c-42cf-a1e5-c0766cc2dca8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADOB-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/25a81259-ff43-48bd-b48d-27dc140b2893

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 21,870; copy number 2: 34,882; copy number 3: 1,561; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:131,491,160–131,521,573, 2 genes (within-gene range 0–1): MIR4784, SMPD4BP.
- chr7:157,513,294–157,518,658, 1 gene: AC006372.2.
- chr16:89,226,807–89,228,692, 1 gene (within-gene range 0–1): AC009113.2.
- chr16:89,707,134–89,720,898, 2 genes (within-gene range 0–1): VPS9D1, VPS9D1-AS1.
- chr17:22,221,221–22,439,033, 9 genes: FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4.
- chr17:78,130,770–78,142,968, 1 gene (within-gene range 0–2): TMC8.
- chr20:26,132,887–26,134,198, 1 gene: AL391119.1.
- chr21:7,744,962–8,761,335, 30 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666.
- chr21:8,996,496–10,613,379, 31 genes: CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4.
- chr22:29,205,896–29,259,597, 1 gene: EMID1.
- chr22:38,130,216–38,150,612, 1 gene (within-gene range 0–1): AL022322.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,266,494–89,310,144, 6 genes, copy number 5: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38.

Autosomal genes at a single copy (total copy number 1): 20,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
